Somatic mutation profile of tumor specimen TCGA-QR-A70N-01A (aliquot TCGA-QR-A70N-01A-12D-A35D-08) from TCGA case TCGA-QR-A70N, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 32.3 years (11,781 days).
Specimen TCGA-QR-A70N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72b57be4-016d-43b0-828b-fe11fcfcaaad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70N-10A (Blood Derived Normal), aliquot TCGA-QR-A70N-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91ca10ae-9db4-45fc-8fc8-a8617d68783b

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Nonsense Mutation 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC40 | c.2104G>A p.V702M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs748948064; called by muse, mutect2, varscan2
- LRRC7 | c.2683G>A p.A895T (on ENST00000651989 / NM_001370785.2; = p.A862T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1455950577, COSV50456565, COSV50534238; called by muse, mutect2, varscan2
- TRAF2 | c.559T>G p.L187V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs754887702; called by muse, mutect2, varscan2
- VHL | c.429C>G p.D143E | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as rs773556807, CD951875, COSV56546162, COSV56565906; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALS2 | c.1489A>G p.R497G | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CD163 | c.580T>A p.S194T | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.078); called by muse, mutect2
- OR52D1 | c.428T>A p.V143D | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2
- PLXNA2 | c.4483A>G p.I1495V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- WARS2 | c.646A>T p.K216* | Nonsense Mutation (SNP) | VAF 17/120 reads (14%) | called by muse, mutect2, varscan2
- ZFC3H1 | c.1975del p.L659* | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | called by mutect2, pindel, varscan2
- COL11A1 | c.3588A>C p.P1196= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- PCDHGA6 | c.51C>A p.L17= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV54032938; called by muse, mutect2
- NSD3 | c.1855+860C>A | Intron (SNP) | VAF 22/47 reads (47%) | catalogued as COSV57617956; called by muse, mutect2, varscan2
